Somatic mutation profile of tumor specimen MP2PRT-PAPJBY-TMP1-A (aliquot MP2PRT-PAPJBY-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPJBY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Precursor cell lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,361 days).
Specimen MP2PRT-PAPJBY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 909ec7e3-db8d-4a8e-abc2-72887f281aa7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPJBY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPJBY-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c96ef0f-389b-4e3d-b5d6-e1103c685437

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Frame Shift Ins 3, Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MFSD12 | c.899T>C p.M300T | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs928221846; called by muse, mutect2, varscan2
- USHBP1 | c.348dup p.D117Rfs*73 | Frame Shift Ins (INS) | VAF 215/621 reads (35%) | catalogued as rs1442016307; called by mutect2, pindel, varscan2
- BTK | c.1040_1041insGACC p.E348Tfs*2 | Frame Shift Ins (INS) | VAF 111/193 reads (58%) | called by mutect2, pindel, varscan2
- ERGIC3 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBL1XR1 | c.422_423dup p.A142* | Frame Shift Ins (INS) | VAF 75/248 reads (30%) | called by mutect2, pindel, varscan2
- RBM12 | c.96C>T p.G32= | Silent (SNP) | VAF 28/520 reads (5%) | catalogued as rs754871778, COSV58294532; called by muse, mutect2
- SIPA1L2 | c.3595C>T p.L1199= | Silent (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
